HCMI case HCM-BROD-0475-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2ae5f389-df9b-46d8-8234-193bc40fe742

Demographics
Sex at birth: male; Year of birth: 1982; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 35.4 years (12,926 days); Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: Yes; Sites of involvement: Pleura.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Fluorouracil + Oxaliplatin; Treatment intent type: Neoadjuvant; Days to treatment start: 17 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 402 days (1.1 years); Days to treatment end: 441 days (1.2 years).
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 0 days.
- Days to follow up: 406 days (1.1 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 406 days (1.1 years).
- Follow-up contact recording only the day: day 451.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 64 kg; BMI: 21.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (1 sample)
- Sample HCM-BROD-0475-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
